Somatic mutation profile of tumor specimen ALCH-B2W9-TTP1-A (aliquot ALCH-B2W9-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2W9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.6 years (22,865 days).
Specimen ALCH-B2W9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cac4a60-bc22-4a23-b6cd-2edca5105983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2W9-NB1-A (Blood Derived Normal), aliquot ALCH-B2W9-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64210b1e-eafb-4435-9b2e-81fcd70bf862

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STXBP5L | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 12/129 reads (9%) | catalogued as rs369496199; called by muse, mutect2
- EDC4 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- FLT1 | c.3128T>A p.L1043H | Missense Mutation (SNP) | VAF 15/481 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RRAD | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- SPATA31D1 | c.3740G>T p.G1247V | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); called by muse, mutect2
- VPS35L | c.1970A>G p.Y657C | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- BIRC3 | c.582T>C p.F194= | Silent (SNP) | VAF 9/221 reads (4%) | called by muse, mutect2
- PCDHA2 | c.2046G>A p.A682= | Silent (SNP) | VAF 7/190 reads (4%) | called by muse, mutect2
- SLC12A2 | c.453G>T p.S151= | Silent (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- STUB1 | c.222G>A p.Q74= | Silent (SNP) | VAF 8/220 reads (4%) | called by muse, mutect2
- EPB41L1 | c.1669-3034C>T | Intron (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- MASP2 | c.412+13G>T | Intron (SNP) | VAF 6/200 reads (3%) | called by muse, mutect2
